FM case AD605 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/13f6b482-82ab-47c2-a062-c8e9316b8568

Male, 42.7 years: Solid pseudopapillary tumor (ICD-O-3 8452/1) of the pancreas; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
